Somatic mutation profile of tumor specimen TCGA-19-1386-01A (aliquot TCGA-19-1386-01A-01W-0643-08) from TCGA case TCGA-19-1386, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.1 years (18,678 days).
Specimen TCGA-19-1386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72729842-720b-44a4-9ebc-395165601d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1386-10C (Blood Derived Normal), aliquot TCGA-19-1386-10C-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e11848f3-ddcd-49df-a69e-2d0f65afb805

The open-access MAF lists 62 somatic variants for this specimen: 40 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 21, Nonsense Mutation 6, Frame Shift Del 2, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131692059, COSV52798756; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.217); catalogued as COSV100035794; called by muse, mutect2
- ATP8B1 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.767); catalogued as COSV99377379; called by muse, mutect2, varscan2
- CALCA | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782155305, COSV100524042; called by muse, mutect2, varscan2
- CCNT2 | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.133); catalogued as COSV99750788; called by muse, mutect2, varscan2
- CD163L1 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs776087881, COSV58024151; called by mutect2, varscan2
- CENPQ | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV100225780; called by muse, mutect2
- CLCF1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104894203, CM066008, COSV100425603; called by muse, varscan2
- COL6A3 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99798952; called by muse, mutect2, varscan2
- FAM135B | c.3418C>T p.H1140Y | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52711693, COSV99416961; called by muse, mutect2
- GGT7 | c.1496G>A p.G499D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100321998; called by muse, mutect2, varscan2
- IGSF10 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 12/215 reads (6%) | catalogued as COSV99180768; called by muse, mutect2
- KLHL40 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs773720799, COSV55134044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP11 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs572680283, COSV57586058; called by muse, mutect2, varscan2
- MAST1 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 26/198 reads (13%) | catalogued as COSV52256882, COSV99263097; called by muse, varscan2
- OPRM1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs201516315, COSV57679855, COSV57679871; called by muse, mutect2, varscan2
- OR13H1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 52/99 reads (53%) | catalogued as COSV100088289; called by muse, mutect2, varscan2
- OR7G2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 288/565 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201831795, COSV59687968; called by muse, mutect2, varscan2
- PAPPA | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100074396; called by muse, mutect2
- PELI2 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 23/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99953506; called by muse, mutect2
- PRKCD | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs778015441, COSV57846686; called by muse, mutect2, varscan2
- RMND1 | c.1080G>A p.R360= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100323698; called by muse, mutect2
- SAMD4B | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as COSV100080415; called by muse, mutect2, varscan2
- SMCR8 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329136; called by muse, mutect2, varscan2
- SNX14 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121604; called by muse, mutect2
- SOAT2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV100037209; called by muse, mutect2, varscan2
- SYNE1 | c.16297C>T p.Q5433* (on ENST00000367255 / NM_182961.4; = p.Q5362* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99567585; called by muse, mutect2
- TACC2 | c.6742T>G p.S2248A (on ENST00000334433; = p.S326A on NM_006997.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV99587174; called by mutect2, varscan2
- TAT | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100587653; called by muse, mutect2, varscan2
- TGM4 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs756064945, COSV99942070; called by muse, mutect2, varscan2
- TLE1 | c.2149G>T p.G717* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as COSV100918908; called by muse, mutect2
- TRIM37 | c.860+2T>C p.X287_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99233061; called by muse, mutect2, varscan2
- VPS50 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100004906; called by muse, mutect2
- ZNF460 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 10/303 reads (3%) | catalogued as COSV100828091; called by muse, mutect2
- ZNF664 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV100544499; called by muse, mutect2, varscan2
- ZNFX1 | c.4069C>T p.H1357Y | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872417; called by muse, mutect2
- RP1 | c.4466C>T p.A1489V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by mutect2, varscan2
- SYT11 | c.733del p.V246Sfs*32 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.1976del p.G659Vfs*8 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- ZSCAN25 | c.987C>G p.H329Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, varscan2
- ALMS1 | c.5922A>G p.A1974= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as rs1440655340, COSV100042747; called by muse, mutect2, varscan2
- ARHGEF5 | c.990G>T p.L330= | Silent (SNP) | VAF 18/513 reads (4%) | catalogued as rs1309784863, COSV99282889; called by muse, mutect2
- CCN4 | c.702C>G p.V234= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99137137; called by muse, mutect2, varscan2
- DBH | c.90G>A p.L30= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99708065; called by muse, mutect2, varscan2
- ETS2 | c.1386C>T p.G462= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs1295048521, COSV62873962; called by muse, varscan2
- JARID2 | c.624G>A p.S208= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as rs1054300362, COSV100521866, COSV100521949; called by muse, mutect2
- KLK15 | c.288G>A p.P96= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs369450682, COSV56827487; called by muse, mutect2, varscan2
- MKI67 | c.1176C>A p.P392= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- OR5L1 | c.309G>A p.L103= | Silent (SNP) | VAF 66/526 reads (13%) | catalogued as rs755837669, COSV100450085; called by muse, mutect2, varscan2
- PCDHGC4 | c.1665G>T p.V555= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as COSV99339107, COSV99340593; called by muse, mutect2
- RAB3GAP2 | c.3441G>A p.Q1147= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100741311; called by muse, mutect2, varscan2
- RAPGEF3 | c.963G>A p.R321= (on ENST00000389212; = p.R279= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs1360087090, COSV99406446; called by muse, mutect2
- RIMBP2 | c.798C>T p.D266= | Silent (SNP) | VAF 540/827 reads (65%) | catalogued as COSV55465593, COSV99900436; called by muse, mutect2, varscan2
- RNF217 | c.969G>A p.T323= (on ENST00000521654 / NM_001286398.2; = p.T31= on NM_152553.5) | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as rs371919329; called by muse, mutect2, varscan2
- SNCAIP | c.2553C>T p.N851= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs762107782, COSV54415752; called by muse, mutect2, varscan2
- STK35 | c.795G>A p.E265= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99852893; called by mutect2, varscan2
- TM2D3 | c.681G>A p.L227= (on ENST00000333202 / NM_078474.3; = p.L201= on NM_025141.3) | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100309813; called by muse, mutect2, varscan2
- TMC1 | c.1701A>G p.S567= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV99919792; called by muse, mutect2, varscan2
- TMEM127 | c.651C>T p.N217= | Silent (SNP) | VAF 59/74 reads (80%) | catalogued as rs759801591, COSV99302494; ClinVar: likely benign; called by muse, mutect2, varscan2
- WASHC2C | c.3951C>T p.A1317= (on ENST00000336378; = p.A1296= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 71/355 reads (20%) | called by muse, mutect2, varscan2
- ZNF536 | c.2370G>A p.Q790= | Silent (SNP) | VAF 164/305 reads (54%) | catalogued as COSV100835333; called by muse, mutect2, varscan2
- TRAT1 | c.-1C>G | 5'UTR (SNP) | VAF 28/236 reads (12%) | catalogued as COSV99849320; called by muse, mutect2
